Somatic mutation profile of tumor specimen BA2738D (aliquot aq-BA2738D) from BEATAML1.0 case 2425, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.8 years (24,415 days).
Specimen BA2738D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a6f8381-bfdf-47f4-81c7-54469ac8c553.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2403D (Solid Tissue Normal), aliquot aq-BA2403D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6be18b36-0fa1-41ea-8fb9-a704881d7896

The open-access MAF lists 32 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, Intron 3, 5'Flank 3, Frame Shift Ins 2, Splice Region 1, RNA 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.1849G>T p.V617F | Missense Mutation (SNP) | VAF 63/154 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs77375493, CM123094, COSV67569051, COSV67571909; ClinVar: risk factor / pathogenic / likely pathogenic / not provided / affects; called by muse, mutect2, varscan2
- C5orf22 | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 79/222 reads (36%) | SIFT tolerated (0.8); PolyPhen benign (0.006); catalogued as COSV57597473; called by muse, mutect2
- CMTR1 | c.440C>A p.P147Q | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.376); catalogued as COSV65092000; called by muse, mutect2
- CNTD1 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs535342634, COSV99890568; called by muse, mutect2, varscan2
- CSMD3 | c.10741G>A p.V3581I (on ENST00000297405 / NM_001363185.1; = p.V3412I on NM_052900.3) | Missense Mutation (SNP) | VAF 34/348 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV52179483, COSV99829101; called by muse, mutect2
- DAGLA | c.1584G>A p.R528= | Splice Region (SNP) | VAF 31/71 reads (44%) | catalogued as rs375778772; called by muse, mutect2, varscan2
- DSCAM | c.3520G>A p.G1174R | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1332241663, COSV68027539; called by muse, mutect2, varscan2
- OBSCN | c.23422G>A p.V7808M | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs763366308, COSV62163272; called by muse, mutect2, varscan2
- PHC3 | c.2494C>A p.Q832K (on ENST00000494943 / NM_001308116.2; = p.Q844K on NM_024947.4) | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.365); catalogued as rs1313622135; called by muse, mutect2, varscan2
- ZRSR2 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 6/74 reads (8%) | catalogued as COSV57063302; called by muse, mutect2
- CAPN13 | c.574C>A p.L192M | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- COL22A1 | c.4629_4630dup p.K1544Tfs*81 | Frame Shift Ins (INS) | VAF 8/30 reads (27%) | called by mutect2, pindel
- FAM120C | c.2035G>T p.A679S | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.388); called by muse, mutect2
- FGD6 | c.3764G>T p.C1255F | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRTAP4-12 | c.54G>T p.E18D | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.239); called by muse, mutect2
- PACC1 | c.923C>A p.A308D | Missense Mutation (SNP) | VAF 60/109 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC2A7 | c.800G>A p.G267D | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TBL1Y | c.1266C>A p.S422R | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.039); called by muse, mutect2
- ZNF292 | c.6279dup p.R2094Tfs*10 | Frame Shift Ins (INS) | VAF 99/273 reads (36%) | called by mutect2, pindel, varscan2
- DNAH9 | c.9111C>T p.N3037= | Silent (SNP) | VAF 68/163 reads (42%) | catalogued as rs139490886; called by muse, mutect2, varscan2
- MMP27 | c.396A>G p.Q132= | Silent (SNP) | VAF 47/133 reads (35%) | called by muse, mutect2, varscan2
- SLC30A8 | c.714C>A p.I238= | Silent (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2, varscan2
- SPTA1 | c.2703C>T p.F901= | Silent (SNP) | VAF 123/270 reads (46%) | catalogued as rs144579942, COSV63755742, COSV63757524, COSV63760789; called by muse, mutect2, varscan2
- TEX13A | c.1002C>T p.S334= | Silent (SNP) | VAF 23/36 reads (64%) | catalogued as rs782618693, COSV61162129; called by muse, mutect2, varscan2
- DYNC1H1 | c.9049-14G>C | Intron (SNP) | VAF 16/218 reads (7%) | called by muse, mutect2
- GOLGA6L17P | n.1114G>A | RNA (SNP) | VAF 56/125 reads (45%) | called by muse, mutect2, varscan2
- KCNT1 | c.377+1349G>A | Intron (SNP) | VAF 52/161 reads (32%) | called by muse, mutect2, varscan2
- MYH11 | c.*104T>C | 3'UTR (SNP) | VAF 31/105 reads (30%) | catalogued as COSV100259644; called by muse, mutect2, varscan2
- OSBPL2 | chr20:62233185 G>A | 5'Flank (SNP) | VAF 24/84 reads (29%) | called by muse, mutect2, varscan2
- PPM1F | c.355+1285G>A | Intron (SNP) | VAF 35/69 reads (51%) | called by muse, mutect2, varscan2
- SYCE1 | chr10:133568155 C>A | 5'Flank (SNP) | VAF 4/26 reads (15%) | catalogued as COSV58216282; called by muse, varscan2
- TSPOAP1 | chr17:58331262 A>G | 5'Flank (SNP) | VAF 30/41 reads (73%) | catalogued as rs1267954074; called by muse, mutect2, varscan2
